Gene-level copy-number profile of specimen HCM-SANG-0297-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37b331d2-a44b-47ca-8423-2e1b89b1083f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0297-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8418aa6b-d13c-436d-8e3f-d540b2760062

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 601; copy number 2: 11,648; copy number 3: 30,156; copy number 4: 12,967; copy number 5: 827; copy number 6: 1,773; copy number 7: 370; copy number 8: 1; copy number 10: 148; copy number 11: 80; copy number 12: 4; copy number 15: 142; copy number 17: 5; copy number 19: 41; copy number 20: 99.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–3): PRB1.
- chr22:16,428,947–16,934,003, 34 genes: SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 890 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:44,066,624–44,066,731, 1 gene, copy number 7: RNU6-381P.
- chr5:44,698,431–45,895,970, 11 genes, copy number 7: AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:63,022,919–64,486,615, 6 genes, copy number 7: AC113420.1, AC025445.1, HTR1A, AC122707.1, RNF180, AC091862.1.
- chr5:101,976,296–103,212,799, 15 genes, copy number 7–8: AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2.
- chr5:177,801,204–177,803,344, 1 gene, copy number 7: AC140125.1.
- chr7:73,567,537–77,462,139, 126 genes, copy number 7 (broad region; genes not listed).
- chr7:78,017,055–79,654,227, 17 genes, copy number 7: MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234.
- chr7:80,742,538–81,770,438, 10 genes, copy number 7: SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:86,643,914–88,226,993, 23 genes, copy number 7 (within-gene range 3–7): GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1.
- chr7:89,882,353–98,870,771, 153 genes, copy number 7 (broad region; genes not listed).
- chr11:63,137,867–63,369,718, 1 gene, copy number 7 (within-gene range 2–7): SLC22A10.
- chr11:63,237,957–63,266,256, 3 genes, copy number 7: AP001880.2, CCND2P1, AP001880.1.
- chr11:67,583,742–67,784,229, 17 genes, copy number 20: GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4.
- chr11:68,980,021–76,444,687, 259 genes, copy number 11–20 (broad region; genes not listed).
- chr11:76,654,169–83,423,516, 107 genes, copy number 7–17 (broad region; genes not listed).
- chr11:107,502,727–109,823,893, 36 genes, copy number 11: ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr11:114,343,052–114,454,123, 6 genes, copy number 12–20 (within-gene range 2–20): AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2.
- chr11:117,427,772–119,381,711, 94 genes, copy number 10–19 (broad region; genes not listed).
- chr11:119,372,706–119,381,613, 1 gene, copy number 10: AP003396.3.
- chr20:30,214,765–30,289,956, 3 genes, copy number 7 (within-gene range 6–7): CFTRP3, LINC01597, AL121762.1.

Autosomal genes at a single copy (total copy number 1): 601. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
